Surgical pathology report (de-identified scan), TCGA case TCGA-NQ-A57I, project TCGA-MESO (Mesothelioma), tissue source site International Genomics Consortium, specimen TCGA-NQ-A57I-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

* Final Report *

ICDD-3
Mesothelioma, biphasic, malignant
9053/3

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Site:
Pleura, parietal
c38.4
JW 12/5/12

Collected:

Accession:

Physician:

PROCEDURE

Biopsy.

SPECIMEN:

A. Pleural biopsy frozen. B. Pleural bx. C. Pleural bx.

HISTORY

Recurrent pleural effusion.

GROSS

A. Specimen labeled as "pleural biopsy" consists of a fragment of fibrous tissue with pink-tan nodules measuring 2.5 x 1.8 x 0.5 cm. Representatively processed for frozen. One piece is submitted TCGA Project.

The specimen is entirely submitted as follows:

1. Frozen section control.
2. Remaining tissue serially sectioned and entirely submitted.

B. Labeled "pleural biopsy" is a tissue vial with clear formalin. No tissue specimen is identified within. Sections none.

C. Received in formalin in a container labeled pleural biopsy perm. #2" are numerous irregular fragments of glistening, mucoid debris with and without areas of hemorrhage (up to 4.3 cm in greatest dimension, 7 x 7 x 2.2 cm in aggregate). Representative sections are submitted in four cassettes.

FROZEN SECTION DIAGNOSIS

A. High-grade malignant neoplasm undifferentiated. Dr. [redacted] is called for frozen section diagnosis at 1:45 p.m. [redacted]

MICROSCOPIC

A and C. Both specimens show similar features of a cellular, high-grade malignancy, appearing as sheets of spindle and epithelioid cells in a fibromyxoid background. The tumor cells display pleomorphic, vesicular, round, elongated and multilobated nuclei, frequent prominent nucleolus and abundant amounts of amphophilic cytoplasm. Mitotic activity is high. There are areas

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

of tumor necrosis and fibroblastic reaction with hemorrhage. Tumor invades fibroadipose soft tissues of chest wall.

To substantiate the initial impression of mesothelioma and to exclude possible pseudomesotheliomatous carcinoma, melanoma and sarcoma, a panel of immunohistochemical stains is performed with appropriately performing positive and negative tissue controls. Results for tumor cells are as follows:

B72.3: Negative
Calretinin: Negative
mCEA: Negative
Mesothelin: Positive, cytoplasmic
Napsin: Negative
TTF1: Positive
S-100: Negative
WT1: Positive (surface cells only)
AE1/3: Positive
CK5: Positive

In addition, a PAS histochemical stain with diastase digestion is performed and shows no evidence of tumor-associated mucin.

These results, in association with histomorphology, support a diagnosis of malignant mesothelioma, biphasic pattern, in this case.

DIAGNOSIS

A, C. Pleural biopsy #1 and #2:
Malignant mesothelioma, biphasic pattern, involving parietal pleura.

B. Pleural biopsy:
No specimen received. [REDACTED]

SUMMARY OF MALIGNANT NEOPLASM: MALIGNANT PLEURAL MESOTHELIOMA

Specimen: Pleural biopsies
Procedure: Biopsy
Specimen Integrity: Portions
Specimen Laterality: Not given
Tumor Site: Not given
Tumor Focality: Not known
Histologic Type: Biphasic
Tumor Extension: N/A
Margins: N/A
Treatment Effect: N/A
Pathological Stage: pT1b NX
*Additional Pathologic Findings: N/A

COMMENT

Printed by: [REDACTED]
Printed on:

[page 3 of 3]
Surg Path Final Report

* Final Report *

Case seen in review by Drs. [REDACTED] who concur with the diagnosis.

Preliminary diagnosis called to Dr. [REDACTED]

[REDACTED] (Electronic Signature)

Completed Action List:

* Order by [REDACTED] MD, [REDACTED] on

Type: Surg Path Final Report

Date:

Status:

Title:

SURG PATH FINAL REPORT

Encounter info:

Printed by:

Printed on:

Page 3 of 3
(End of Report)

I/FPA Discrepancy		X
Reviewed by [REDACTED]	11/29/12	12/4/12

Source: NCI Genomic Data Commons file f1030d00-018d-4f5c-8f2f-dcd003af26d6 (TCGA-NQ-A57I.5BAF43B9-899B-499A-A326-199ACD954BF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).